Somatic mutation profile of tumor specimen TCGA-N6-A4VG-01A (aliquot TCGA-N6-A4VG-01A-31D-A28R-08) from TCGA case TCGA-N6-A4VG, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Age at diagnosis: 77.8 years (28,428 days).
Specimen TCGA-N6-A4VG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53d6273b-4a7f-4fdc-a791-d3413b4ec33a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N6-A4VG-10A (Blood Derived Normal), aliquot TCGA-N6-A4VG-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab13725f-2f2c-43f9-935b-1587810293cf

The open-access MAF lists 56 somatic variants for this specimen: 39 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 16, Splice Site 3, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 50/84 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 30/34 reads (88%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS12 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367793699; called by muse, mutect2, varscan2
- DNAH11 | c.13429G>A p.E4477K | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs551275210; called by muse, mutect2, varscan2
- FXR1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV59764578; called by muse, mutect2, varscan2
- GPR37 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58258556; called by muse, mutect2, varscan2
- HYAL2 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as rs782485249; called by muse, mutect2
- IGKV1-17 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs1312167781; called by muse, mutect2, varscan2
- LRP3 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1007527829; called by muse, mutect2
- MYC | c.1120T>C p.F374L (on ENST00000377970; = p.F389L on NM_002467.6) | Missense Mutation (SNP) | VAF 128/265 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52373150; called by muse, mutect2, varscan2
- RXFP2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs373570227; called by muse, mutect2, varscan2
- SLC12A5 | c.2717G>A p.R906H (on ENST00000454036 / NM_001134771.2; = p.R883H on NM_020708.5) | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV99714960; called by muse, mutect2, varscan2
- SSX7 | c.331-1G>C p.X111_splice | Splice Site (SNP) | VAF 70/106 reads (66%) | catalogued as rs781841519; called by muse, mutect2, varscan2
- UGT1A7 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as rs752380757, COSV60839109; called by muse, mutect2, varscan2
- ALKBH2 | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK11A | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CDK11A | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- FASTKD5 | c.2236C>G p.R746G | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FOXA2 | c.664C>T p.R222C (on ENST00000377115 / NM_153675.3; = p.R228C on NM_021784.5) | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM2 | c.8638T>C p.F2880L | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GMDS | c.478G>C p.G160R | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1730T>G p.V577G | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HPX | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10Z1 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PHF19 | c.876C>A p.H292Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PRDM1 | c.1267A>C p.N423H | Missense Mutation (SNP) | VAF 83/527 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- RAPGEF6 | c.4523C>A p.P1508H | Missense Mutation (SNP) | VAF 74/82 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RPN2 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SCLT1 | c.801T>A p.H267Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDF2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SGSM1 | c.689G>T p.S230I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC2A14 | c.575T>G p.V192G | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- TAF1 | c.3902C>A p.T1301N (on ENST00000373790 / NM_138923.4; = p.T1322N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TGIF2 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TPTE | c.173+2T>A p.X58_splice | Splice Site (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5311G>A p.A1771T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YTHDF1 | c.217del p.A73Lfs*108 | Frame Shift Del (DEL) | VAF 38/136 reads (28%) | called by mutect2, pindel, varscan2
- ZBTB7B | c.323C>A p.T108K (on ENST00000292176; = p.T142K on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF404 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C8orf76 | c.558G>A p.A186= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as rs939211239, COSV52690022; called by muse, mutect2, varscan2
- CA13 | c.675C>G p.A225= | Silent (SNP) | VAF 15/250 reads (6%) | called by muse, mutect2
- CNTNAP1 | c.3090G>A p.R1030= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs1452617069; called by muse, mutect2
- CSMD2 | c.2280C>T p.S760= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs145279639; called by muse, mutect2, varscan2
- DNAH2 | c.8664C>T p.I2888= | Silent (SNP) | VAF 39/42 reads (93%) | catalogued as rs758667161, COSV66718511; called by muse, mutect2, varscan2
- FARP2 | c.1167A>C p.S389= | Silent (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- GRIK1 | c.561A>G p.Q187= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- KLHDC3 | c.729G>C p.S243= | Silent (SNP) | VAF 33/235 reads (14%) | called by muse, mutect2, varscan2
- MEI1 | c.1116G>A p.R372= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV55900176; called by muse, mutect2, varscan2
- MYRIP | c.1671G>A p.S557= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs757801543; called by muse, mutect2, varscan2
- NTRK2 | c.2196G>A p.T732= (on ENST00000323115 / NM_001369534.1; = p.T748= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as rs1010204088; called by muse, mutect2, varscan2
- REXO1 | c.363C>T p.S121= | Silent (SNP) | VAF 19/21 reads (90%) | catalogued as rs769826037; called by muse, mutect2, varscan2
- RIF1 | c.5268C>T p.D1756= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs553538022, COSV99691032; called by muse, mutect2, varscan2
- SEMA5A | c.3162T>C p.H1054= | Silent (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- SLC10A7 | c.801C>T p.D267= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV53879833; called by muse, mutect2, varscan2
- ZNF512B | c.156C>T p.P52= | Silent (SNP) | VAF 127/236 reads (54%) | catalogued as rs769204704, COSV99412567; called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407721 G>T | 5'Flank (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
